Somatic mutation profile of tumor specimen CDDP-ABIZ-TTP2-A (aliquot CDDP-ABIZ-TTP2-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABIZ, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67 years.
Specimen CDDP-ABIZ-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c76ef41-a6b2-4305-bfc1-075254d03ddc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABIZ-NB1-A (Blood Derived Normal), aliquot CDDP-ABIZ-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7b1d659-9c23-4d98-81d9-4f2ff226b1c9

The open-access MAF lists 394 somatic variants for this specimen: 267 protein-altering or splice-affecting, 76 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 232, Silent 76, Intron 26, Nonsense Mutation 13, Frame Shift Del 11, 3'UTR 9, Splice Site 7, RNA 7, 5'UTR 4, 3'Flank 3, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 22/752 reads (3%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs1004981575, COSV59582892, COSV59590977; called by muse, mutect2
- KCNT1 | c.2741G>A p.R914H (on ENST00000488444; = p.R933H on NM_020822.3) | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1023136319, COSV53698351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1334T>C p.V445A | Missense Mutation (SNP) | VAF 88/406 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV53965953; called by muse, varscan2
- ABCC9 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 71/397 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV53965967; called by muse, mutect2, varscan2
- ABLIM2 | c.1012A>T p.S338C | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV56401785; called by muse, mutect2, varscan2
- ADAMTS12 | c.4275G>T p.E1425D | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV61258691; called by muse, mutect2, varscan2
- ADGRV1 | c.16321A>C p.M5441L | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV67981190; called by muse, mutect2, varscan2
- ADRB1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100992258, COSV65167734; called by muse, mutect2, varscan2
- ANK1 | c.5101C>A p.Q1701K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV55876909; called by muse, mutect2
- ANKAR | c.4036A>G p.I1346V | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51462050; called by muse, mutect2, varscan2
- AP002512.3 | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 122/377 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54405926, COSV99687874; called by muse, mutect2, varscan2
- B3GALT6 | c.821A>G p.Q274R | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV55418385; called by muse, mutect2, varscan2
- BCL11A | c.380T>G p.I127R | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV59626634; called by muse, mutect2
- BMPR1B | c.411G>C p.L137F | Missense Mutation (SNP) | VAF 138/423 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52775815; called by muse, mutect2, varscan2
- BOLL | c.86C>G p.T29R | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV56573705; called by muse, mutect2, varscan2
- C2orf16 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.011); catalogued as COSV71614035; called by muse, mutect2, varscan2
- C7 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs752466445, COSV57472481; called by muse, mutect2, varscan2
- CACHD1 | c.3655G>A p.G1219R | Missense Mutation (SNP) | VAF 114/482 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs144669889, COSV51550558; called by mutect2, varscan2
- CACNG7 | c.650A>T p.Y217F | Missense Mutation (SNP) | VAF 108/345 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55813663; called by muse, mutect2, varscan2
- CARMIL2 | c.2413C>T p.R805C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs752624862, COSV58025920; called by muse, mutect2, varscan2
- CCNL1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 79/330 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55816696; called by muse, mutect2, varscan2
- CD96 | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51914237; called by muse, mutect2, varscan2
- CEP126 | c.2756C>T p.P919L | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.147); catalogued as rs370774279; called by muse, mutect2, varscan2
- CFAP46 | c.4588G>T p.V1530F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63952113; called by muse, mutect2, varscan2
- CHD7 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs587783435, CM149843, COSV71107289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHL1 | c.2468G>T p.S823I (on ENST00000397491 / NM_001253387.1; = p.S839I on NM_006614.4) | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56589409; called by muse, mutect2, varscan2
- CIITA | c.3081C>G p.I1027M | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60855279, COSV60861041; called by muse, mutect2, varscan2
- CLRN1 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 209/964 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as COSV58993258; called by mutect2, varscan2
- COL11A1 | c.473A>C p.N158T | Missense Mutation (SNP) | VAF 57/439 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV62175098; called by muse, mutect2, varscan2
- COL22A1 | c.1315C>A p.P439T | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs762019899; called by muse, mutect2, varscan2
- COL6A6 | c.1934T>C p.M645T | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV62020788; called by muse, mutect2, varscan2
- CPNE3 | c.656A>T p.N219I | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV52205088; called by muse, mutect2, varscan2
- CRACD | c.3127C>A p.P1043T | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51727310; called by muse, mutect2, varscan2
- CREB3L3 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 163/414 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV50178496; called by muse, mutect2, varscan2
- CRYBG3 | c.8405A>T p.N2802I | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51710579; called by muse, mutect2, varscan2
- CSMD1 | c.3997C>A p.L1333I (on ENST00000520002; = p.L1332I on NM_033225.6) | Missense Mutation (SNP) | VAF 150/449 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV59299816; called by muse, mutect2, varscan2
- CTSG | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 2235/2699 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53535022; called by mutect2, varscan2
- CYP1A1 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65696821; called by muse, mutect2, varscan2
- DECR2 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV54793643; called by muse, mutect2, varscan2
- DHCR7 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 312/580 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62794752; called by muse, mutect2, varscan2
- DHCR7 | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 317/584 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142808899, CM056322, COSV62794760; called by muse, mutect2, varscan2
- DLGAP2 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs777261867, COSV101421623; called by muse, mutect2, varscan2
- DOP1B | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.063); catalogued as rs545711530, COSV67692646; called by muse, mutect2, varscan2
- DRD3 | c.40A>T p.T14S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV55679347; called by muse, mutect2, varscan2
- DSG3 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774736138, COSV57124224; called by muse, mutect2
- DTHD1 | c.2111G>A p.R704H (on ENST00000456874; = p.R539H on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/486 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as rs1228231249, COSV62628586; called by muse, mutect2, varscan2
- DTX3 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV54085381; called by muse, mutect2, varscan2
- EBLN1 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 82/800 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV69370168; called by muse, mutect2, varscan2
- EFCAB1 | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100030979; called by muse, mutect2, varscan2
- EFCAB13 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV58946945; called by muse, mutect2, varscan2
- EMC7 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV56626886; called by muse, mutect2, varscan2
- ERBB3 | c.2354T>G p.L785R | Missense Mutation (SNP) | VAF 271/704 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57249128; called by muse, mutect2, varscan2
- ERCC6 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 93/400 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs562828066, COSV63388749; called by muse, mutect2, varscan2
- F13A1 | c.1128G>T p.W376C | Missense Mutation (SNP) | VAF 184/582 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM060260, COSV53555912; called by muse, mutect2, varscan2
- F2R | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 223/689 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV59928725; called by muse, mutect2, varscan2
- F5 | c.6091C>A p.Q2031K | Missense Mutation (SNP) | VAF 75/502 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.029); catalogued as COSV63122220; called by muse, mutect2, varscan2
- FBLN2 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 127/556 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV55482343; called by muse, mutect2, varscan2
- FBN2 | c.5677C>A p.R1893S | Missense Mutation (SNP) | VAF 151/442 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV52498971; called by muse, mutect2, varscan2
- FIP1L1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60994915; called by muse, mutect2, varscan2
- FLNC | c.6052C>G p.R2018G | Missense Mutation (SNP) | VAF 91/444 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV100367922, COSV57952809; called by muse, mutect2, varscan2
- GABRA4 | c.1510C>A p.P504T | Missense Mutation (SNP) | VAF 123/392 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV51924800; called by muse, mutect2, varscan2
- GABRG1 | c.628G>T p.G210* | Nonsense Mutation (SNP) | VAF 36/187 reads (19%) | catalogued as COSV54951497; called by muse, mutect2, varscan2
- GAS6 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 48/336 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as rs778770154, COSV59848509; called by muse, mutect2, varscan2
- GNAI3 | c.639C>G p.H213Q | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV63983434; called by muse, mutect2, varscan2
- GPD2 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752343390, COSV60091257; called by muse, mutect2, varscan2
- GPR139 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 170/489 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750115024, COSV100430045, COSV58502171; called by muse, mutect2, varscan2
- GPR78 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.029); catalogued as COSV66762718; called by muse, mutect2, varscan2
- GPRIN1 | c.1456A>T p.K486* | Nonsense Mutation (SNP) | VAF 33/175 reads (19%) | catalogued as COSV56136284; called by muse, mutect2, varscan2
- GRID2 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56186431; called by muse, mutect2, varscan2
- GRIK2 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs778431133, COSV59718340; called by muse, mutect2, varscan2
- GRM7 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as rs1312633998, COSV100735140, COSV63130661; called by muse, mutect2
- GRM8 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 71/367 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58813558; called by muse, mutect2, varscan2
- GRM8 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV58813587; called by muse, mutect2, varscan2
- HACD1 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 41/516 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV63516158; called by muse, mutect2
- HAS1 | c.646C>A p.R216S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55786767, COSV55786789; called by muse, mutect2, varscan2
- HELLS | c.861G>T p.M287I | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53295471; called by muse, mutect2, varscan2
- HMX1 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68771570; called by muse, mutect2, varscan2
- IBTK | c.3086A>G p.D1029G | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs1300595718, COSV60391778; called by muse, mutect2, varscan2
- IFT122 | c.1484G>A p.G495E (on ENST00000348417 / NM_052989.3; = p.G436E on NM_018262.4) | Missense Mutation (SNP) | VAF 125/551 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56199953; called by muse, mutect2, varscan2
- IL36B | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV52085060; called by muse, mutect2, varscan2
- IQSEC1 | c.2206G>C p.G736R | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as COSV56222475; called by muse, mutect2, varscan2
- IRF7 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.319); catalogued as COSV52753213; called by muse, mutect2
- ISYNA1 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV53211717; called by muse, mutect2, varscan2
- ITIH5 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 312/473 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56901066; called by muse, mutect2, varscan2
- KCNA4 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.678); catalogued as COSV60251079, COSV60251271; called by muse, mutect2, varscan2
- KCNK2 | c.766G>C p.A256P (on ENST00000444842 / NM_001017425.3; = p.A241P on NM_014217.4) | Missense Mutation (SNP) | VAF 113/279 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV67204248; called by muse, mutect2, varscan2
- KDM3B | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV58688970; called by muse, varscan2
- KIF1C | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57903556; called by muse, mutect2, varscan2
- KLC2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 153/251 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs549150930, COSV100385128, COSV57581953; called by muse, mutect2, varscan2
- KRT71 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57289477; called by muse, mutect2, varscan2
- KRTAP24-1 | c.436C>A p.R146S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV61089169, COSV61090157; called by muse, mutect2
- KRTAP4-2 | c.362G>C p.C121S | Missense Mutation (SNP) | VAF 129/347 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs746850245, COSV66658192; called by muse, mutect2, varscan2
- LAMA5 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs758209373, COSV53355896; called by muse, mutect2, varscan2
- LAMC3 | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV63089489; called by muse, mutect2, varscan2
- LAMC3 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | catalogued as COSV63089493; called by muse, mutect2, varscan2
- LIPI | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 32/156 reads (21%) | catalogued as COSV60709544; called by muse, varscan2
- LPIN1 | c.824G>T p.W275L | Missense Mutation (SNP) | VAF 97/768 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56763457; called by muse, mutect2, varscan2
- LRP1B | c.10402G>C p.E3468Q | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV67199606, COSV67278847; called by muse, mutect2, varscan2
- LRRK2 | c.5327T>G p.L1776R | Missense Mutation (SNP) | VAF 67/504 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54165377; called by muse, mutect2, varscan2
- MCHR2 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.926); catalogued as rs1271760583, COSV56001037; called by muse, varscan2
- MED12L | c.5719C>A p.Q1907K | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.093); catalogued as COSV56373104; called by muse, varscan2
- MED16 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs777186635; called by muse, varscan2
- MEFV | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 98/264 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54819914; called by muse, mutect2, varscan2
- MS4A14 | c.787A>T p.M263L | Missense Mutation (SNP) | VAF 118/471 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55733881; called by muse, mutect2, varscan2
- MUC16 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 171/450 reads (38%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV67454557, COSV67506671; called by muse, mutect2, varscan2
- MYH15 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56306777; called by muse, mutect2, varscan2
- MYH15 | c.2492G>T p.R831I | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56306790, COSV99071906; called by muse, varscan2
- MYH2 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV55434247; called by muse, mutect2, varscan2
- NALCN | c.2071C>A p.H691N | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51923425, COSV51925126; called by muse, mutect2, varscan2
- NAV3 | c.6464C>T p.T2155I (on ENST00000397909 / NM_001024383.2; = p.T2133I on NM_014903.6) | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57069397; called by muse, mutect2, varscan2
- NBAS | c.6584A>G p.N2195S | Missense Mutation (SNP) | VAF 221/566 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV55716267; called by muse, mutect2, varscan2
- NCAN | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV53048484; called by muse, mutect2, varscan2
- NIBAN3 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV56306641; called by muse, mutect2, varscan2
- NOBOX | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 75/333 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV56193251, COSV56194121; called by muse, mutect2, varscan2
- NOX4 | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as COSV54448559; called by muse, mutect2, varscan2
- NPAP1 | c.1298C>A p.A433D | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV100274881, COSV61505529; called by muse, mutect2, varscan2
- NPAS3 | c.2043C>A p.S681R (on ENST00000356141 / NM_001164749.2; = p.S649R on NM_022123.3) | Missense Mutation (SNP) | VAF 114/389 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV60826403; called by muse, mutect2, varscan2
- NR0B1 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 188/314 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV66763786; called by muse, mutect2, varscan2
- NTRK3 | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 83/481 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62299082; called by muse, mutect2, varscan2
- NUMBL | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs368177644; called by muse, varscan2
- OCA2 | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 131/644 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62341806, COSV62358805; called by muse, mutect2, varscan2
- OR10K1 | c.418del p.V140Cfs*5 | Frame Shift Del (DEL) | VAF 55/453 reads (12%) | catalogued as COSV56872425; called by mutect2, pindel, varscan2
- OR11H1 | c.74G>T p.W25L | Missense Mutation (SNP) | VAF 88/1288 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99421820; called by muse, mutect2
- OR11H6 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 129/308 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59643951; called by muse, mutect2, varscan2
- OR11H6 | c.839C>A p.P280Q | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59643956; called by muse, mutect2, varscan2
- OR14A16 | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62926315; called by muse, mutect2, varscan2
- OR2A12 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68821170; called by muse, mutect2, varscan2
- OR2T27 | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV61283797; called by muse, mutect2
- OR5D13 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV62333131, COSV62335171; called by muse, mutect2, varscan2
- OR5T3 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV57379899; called by muse, mutect2, varscan2
- OR6N1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625192; called by muse, mutect2, varscan2
- OSBPL5 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV55140410; called by muse, mutect2, varscan2
- OTC | c.577T>A p.W193R | Missense Mutation (SNP) | VAF 284/518 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM062974, CM062975; called by muse, varscan2
- OTOG | c.4511C>G p.T1504S | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61128371; called by muse, mutect2, varscan2
- OTX2 | c.332C>A p.A111D (on ENST00000408990 / NM_172337.3; = p.A119D on NM_021728.4) | Missense Mutation (SNP) | VAF 315/857 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV59765674; called by muse, mutect2, varscan2
- PALD1 | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV54970450, COSV54971844, COSV54976023; called by muse, mutect2, varscan2
- PCARE | c.1799T>A p.L600H | Missense Mutation (SNP) | VAF 90/778 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59053851; called by muse, mutect2, varscan2
- PCDH15 | c.2221G>C p.A741P | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57258330, COSV57279942; called by muse, mutect2, varscan2
- PCDHB7 | c.2296A>G p.K766E | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV50758175; called by muse, mutect2, varscan2
- PCK1 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 63/504 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV60126891; called by muse, mutect2, varscan2
- PDE4A | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53351948; called by muse, mutect2, varscan2
- PJA1 | c.907G>T p.G303C (on ENST00000361478 / NM_145119.4; = p.G115C on NM_022368.5) | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.831); catalogued as COSV64052830; called by muse, mutect2, varscan2
- PLXNA2 | c.4436G>T p.G1479V | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65438753; called by muse, mutect2, varscan2
- PLXNC1 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51572012; called by muse, mutect2, varscan2
- PNP | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 451/878 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV64091865; called by muse, mutect2, varscan2
- POLA1 | c.2905G>T p.A969S | Missense Mutation (SNP) | VAF 97/189 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66883697; called by muse, mutect2, varscan2
- POLA1 | c.2906C>T p.A969V | Missense Mutation (SNP) | VAF 96/189 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66884802; called by muse, mutect2, varscan2
- POLQ | c.3841C>T p.Q1281* | Nonsense Mutation (SNP) | VAF 70/360 reads (19%) | catalogued as COSV51748366; called by muse, varscan2
- PPP1R3C | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53287905; called by muse, mutect2, varscan2
- PRSS41 | c.664C>A p.Q222K | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV68786255; called by muse, mutect2, varscan2
- PSMA3 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 39/324 reads (12%) | catalogued as COSV53616694; called by muse, mutect2, varscan2
- PTPRD | c.5692C>A p.R1898S | Missense Mutation (SNP) | VAF 127/335 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV61934701; called by muse, mutect2, varscan2
- PTPRU | c.3083G>T p.R1028L | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759323710, COSV60522856, COSV60524080; called by muse, mutect2, varscan2
- PXDNL | c.3052C>A p.L1018M | Missense Mutation (SNP) | VAF 65/393 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62483080, COSV62486738; called by muse, mutect2, varscan2
- R3HDML | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53835506; called by muse, mutect2, varscan2
- RAD51D | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 192/561 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.754); catalogued as COSV50100564, COSV50100860; called by muse, mutect2, varscan2
- RASL11B | c.248T>A p.L83H | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV50534881; called by muse, mutect2, varscan2
- RBM42 | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV52547251; called by muse, mutect2, varscan2
- RIMS2 | c.1771G>T p.G591* (on ENST00000666250 / NM_001348490.2; = p.G399* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/203 reads (12%) | catalogued as COSV51665503; called by muse, mutect2, varscan2
- RIMS2 | c.3799C>A p.P1267T | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV51728990; called by muse, mutect2, varscan2
- ROBO1 | c.4298A>T p.H1433L | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1330754161; called by muse, mutect2, varscan2
- ROBO2 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1220003348, COSV59909672; called by muse, mutect2, varscan2
- RPA1 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV54608059; called by muse, mutect2, varscan2
- RPA1 | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV54608073; called by muse, mutect2, varscan2
- SAGE1 | c.326C>A p.A109D | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV61012185; called by muse, mutect2, varscan2
- SAMSN1 | c.1034del p.G345Efs*64 | Frame Shift Del (DEL) | VAF 78/657 reads (12%) | catalogued as COSV99581989; called by pindel, varscan2
- SCN10A | c.5659G>A p.A1887T | Missense Mutation (SNP) | VAF 106/642 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV71860791; called by muse, mutect2, varscan2
- SCN10A | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 135/718 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.275); catalogued as COSV71860793; called by muse, mutect2, varscan2
- SGPL1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV54736594; called by muse, varscan2
- SHANK1 | c.2209C>A p.Q737K | Missense Mutation (SNP) | VAF 90/381 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV53246288; called by muse, mutect2, varscan2
- SHISA9 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV69633153; called by muse, mutect2, varscan2
- SIGLEC9 | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 117/393 reads (30%) | catalogued as COSV51583264; called by muse, mutect2, varscan2
- SIX6 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 116/337 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100576550, COSV59801813; called by muse, mutect2, varscan2
- SLC15A4 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV104385838, COSV57160896; called by muse, mutect2, varscan2
- SLC15A4 | c.1340C>A p.A447D | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57160900; called by muse, mutect2, varscan2
- SLC17A6 | c.1226G>T p.R409I | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54134584, COSV54135594; called by muse, mutect2, varscan2
- SLC24A2 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 250/556 reads (45%) | catalogued as COSV53860216; called by muse, mutect2, varscan2
- SLC39A12 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 455/963 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV66196510; called by muse, mutect2, varscan2
- SLC5A5 | c.962del p.P321Qfs*47 | Frame Shift Del (DEL) | VAF 235/641 reads (37%) | catalogued as COSV55832719; called by mutect2, pindel, varscan2
- SLC6A18 | c.1053G>T p.M351I | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV57250249; called by muse, mutect2, varscan2
- SLITRK1 | c.922G>C p.G308R | Missense Mutation (SNP) | VAF 82/504 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV65674800; called by muse, mutect2, varscan2
- SLITRK3 | c.903T>A p.S301R | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV53846673; called by muse, mutect2, varscan2
- SPAG17 | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.277); catalogued as COSV60455468, COSV60471493; called by muse, mutect2, varscan2
- SPATA31D1 | c.4007C>A p.S1336Y | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV61193991; called by muse, mutect2, varscan2
- SPTA1 | c.2328A>T p.E776D | Missense Mutation (SNP) | VAF 129/828 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV63750748; called by muse, mutect2, varscan2
- SPTA1 | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 99/339 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV63750752; called by muse, mutect2, varscan2
- STX3 | c.323G>T p.R108M | Missense Mutation (SNP) | VAF 74/369 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV55696366; called by muse, mutect2, varscan2
- STYK1 | c.776T>C p.M259T | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1255367507, COSV50012693; called by muse, mutect2, varscan2
- SULF2 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 272/716 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737296, COSV63414896; called by muse, mutect2, varscan2
- TENT2 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 75/246 reads (30%) | catalogued as COSV57135233; called by muse, mutect2, varscan2
- THSD1 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51627338; called by muse, mutect2, varscan2
- TIAM2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 69/494 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs773676319, COSV59693028; called by muse, mutect2, varscan2
- TMEM18 | c.164A>C p.H55P | Missense Mutation (SNP) | VAF 143/284 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV55243594; called by muse, mutect2, varscan2
- TRAK2 | c.1349A>T p.E450V | Missense Mutation (SNP) | VAF 236/618 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60270978; called by muse, mutect2, varscan2
- TRPS1 | c.3197G>T p.S1066I (on ENST00000220888 / NM_001330599.2; = p.S1079I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 263/871 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55231774; called by muse, mutect2, varscan2
- TTLL9 | c.196del p.E66Kfs*2 | Frame Shift Del (DEL) | VAF 112/374 reads (30%) | catalogued as rs1265699101; called by mutect2, pindel, varscan2
- UNC45B | c.2741C>G p.A914G | Missense Mutation (SNP) | VAF 171/465 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52093627; called by muse, mutect2, varscan2
- USP25 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV53482541; called by muse, mutect2, varscan2
- USP44 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1471847097, COSV51562820; called by muse, mutect2, varscan2
- ZBED4 | c.3144G>T p.R1048S | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53464514; called by muse, mutect2, varscan2
- ZBTB20 | c.1756A>G p.T586A (on ENST00000474710 / NM_001164342.2; = p.T513A on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV61846109; called by muse, mutect2, varscan2
- ZBTB41 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV66358866; called by muse, mutect2, varscan2
- ZNF106 | c.3410G>T p.R1137L | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV55514940; called by muse, mutect2, varscan2
- ZNF284 | c.235+1G>T p.X79_splice | Splice Site (SNP) | VAF 62/227 reads (27%) | catalogued as COSV69690964; called by muse, mutect2, varscan2
- ZNF385C | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs782592604; called by muse, mutect2
- ZNF454 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 63/503 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs372847132; called by muse, mutect2, varscan2
- ZNF479 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 172/544 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV58639805; called by muse, mutect2, varscan2
- ZNF518B | c.617T>G p.V206G | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58721876; called by muse, mutect2, varscan2
- ZNF606 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 86/375 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs780298009, COSV62045740; called by muse, mutect2, varscan2
- ZNF665 | c.1316A>T p.H439L (on ENST00000600412; = p.H504L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67214145; called by muse, mutect2, varscan2
- ABCA4 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- ACTL8 | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- AKAP13 | c.6017_6018del p.E2006Vfs*25 (on ENST00000394518 / NM_007200.5; = p.E2010Vfs*25 on NM_006738.6) | Frame Shift Del (DEL) | VAF 50/272 reads (18%) | called by pindel, varscan2
- ATP8A2 | c.517_518del p.G173Rfs*22 | Frame Shift Del (DEL) | VAF 64/274 reads (23%) | called by pindel, varscan2
- C5AR2 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 128/531 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CACNA1B | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CENATAC | c.897_906del p.F300Sfs*21 | Frame Shift Del (DEL) | VAF 19/167 reads (11%) | called by mutect2, pindel
- COL14A1 | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL23A1 | c.1150-1G>T p.X384_splice | Splice Site (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- CPEB3 | c.1162del p.A388Qfs*6 | Frame Shift Del (DEL) | VAF 34/127 reads (27%) | called by mutect2, pindel, varscan2
- DCAF8L1 | c.710G>C p.G237A | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DPP10 | c.1160C>A p.T387K | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DPP6 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 143/363 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- EFCAB8 | c.2537T>A p.V846E | Missense Mutation (SNP) | VAF 81/652 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- EPHA6 | c.451-4_457delinsTTTTTTGTTTT p.X151_splice | Splice Site (ONP) | VAF 8/100 reads (8%) | called by mutect2*, pindel
- FSIP2 | c.3012A>C p.E1004D | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRK3 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM2 | c.1524G>T p.E508D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 90/501 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- KIF1C | c.608+1G>T p.X203_splice | Splice Site (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- KLHL33 | c.433del p.A145Lfs*40 | Frame Shift Del (DEL) | VAF 294/681 reads (43%) | called by mutect2, pindel, varscan2
- LGALS9B | c.975G>C p.Q325H (on ENST00000423676 / NM_001367292.1; = p.Q324H on NM_001042685.2) | Missense Mutation (SNP) | VAF 44/561 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, varscan2
- LTN1 | c.2893-1G>A p.X965_splice | Splice Site (SNP) | VAF 16/85 reads (19%) | called by muse, varscan2
- MAGI1 | c.3014T>C p.M1005T (on ENST00000402939 / NM_001033057.2; = p.M1034T on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- MALRD1 | c.3554G>T p.G1185V | Missense Mutation (SNP) | VAF 25/391 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MTIF3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 20/564 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- MYH8 | c.3609G>T p.M1203I | Missense Mutation (SNP) | VAF 120/599 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO19 | c.720G>A p.Q240= | Splice Region (SNP) | VAF 31/148 reads (21%) | called by muse, mutect2, varscan2
- MYOT | c.532-2A>C p.X178_splice | Splice Site (SNP) | VAF 74/524 reads (14%) | called by muse, mutect2, varscan2
- MYPN | c.2443dup p.I815Nfs*36 | Frame Shift Ins (INS) | VAF 49/271 reads (18%) | called by mutect2, pindel, varscan2
- NLGN4X | c.2051C>A p.S684* | Nonsense Mutation (SNP) | VAF 268/457 reads (59%) | called by muse, mutect2, varscan2
- NLRP2 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 39/1447 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); called by muse, mutect2
- OCSTAMP | c.1181C>A p.A394D | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- OR14A16 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- OTOP1 | c.1216dup p.W406Lfs*11 | Frame Shift Ins (INS) | VAF 36/275 reads (13%) | called by mutect2, pindel, varscan2
- PDE8B | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 146/801 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PIANP | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, mutect2
- PLA2G12A | c.179A>T p.D60V | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POF1B | c.236A>G p.K79R | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); called by muse, mutect2
- POTEI | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 102/820 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- POU3F3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PPP2R2A | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRAMEF12 | c.1306C>A p.L436M | Missense Mutation (SNP) | VAF 96/616 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM9 | c.1092A>C p.E364D | Missense Mutation (SNP) | VAF 133/772 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PREX1 | c.173T>G p.L58W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PSMC6 | c.246A>T p.K82N (on ENST00000612399; = p.K68N on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RNF144B | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 22/337 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SDCCAG8 | c.984del p.D328Efs*13 | Frame Shift Del (DEL) | VAF 177/667 reads (27%) | called by pindel, varscan2
- SLC22A9 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SLC3A2 | c.463del p.A155Rfs*16 | Frame Shift Del (DEL) | VAF 87/344 reads (25%) | called by mutect2, pindel, varscan2
- SLC6A1 | c.1339T>A p.F447I | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOHLH1 | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TAOK3 | c.1829A>T p.K610I | Missense Mutation (SNP) | VAF 87/685 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIM65 | c.412_414+7del p.X138_splice | Splice Site (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- UBA3 | c.1071A>T p.E357D | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF419 | c.1370G>A p.C457Y | Missense Mutation (SNP) | VAF 37/479 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF429 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 130/378 reads (34%) | called by muse, mutect2, varscan2
- ACE | c.1972C>A p.R658= | Silent (SNP) | VAF 131/909 reads (14%) | catalogued as COSV52004891; called by muse, mutect2, varscan2
- ADAMTS5 | c.486C>A p.R162= | Silent (SNP) | VAF 64/306 reads (21%) | catalogued as COSV53177203; called by muse, mutect2, varscan2
- ANK1 | c.5100G>A p.L1700= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV55876924; called by muse, mutect2
- ANKRD18B | c.1179G>T p.V393= | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- BAZ1A | c.4068A>G p.R1356= | Silent (SNP) | VAF 94/1304 reads (7%) | called by muse, mutect2
- C2orf42 | c.315G>T p.T105= | Silent (SNP) | VAF 82/403 reads (20%) | catalogued as rs781449735, COSV52449372; called by muse, mutect2, varscan2
- CCDC137 | c.240G>A p.P80= | Silent (SNP) | VAF 131/454 reads (29%) | catalogued as COSV100235704; called by muse, mutect2, varscan2
- CERT1 | c.1488C>T p.V496= (on ENST00000405807 / NM_001130105.1; = p.V368= on NM_005713.3) | Silent (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- CLASP1 | c.30G>A p.A10= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as rs368499126; called by muse, mutect2, varscan2
- CLINT1 | c.957C>T p.S319= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV51622601; called by muse, mutect2, varscan2
- COL18A1 | c.3027A>T p.P1009= (on ENST00000359759 / NM_130444.3; = p.P774= on NM_030582.4) | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1004485966; called by muse, mutect2, varscan2
- CRHR1 | c.738C>A p.I246= (on ENST00000398285 / NM_001145146.2; = p.I217= on NM_004382.5) | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as COSV53276871, COSV53278695; called by muse, mutect2, varscan2
- CST1 | c.93G>T p.P31= | Silent (SNP) | VAF 200/511 reads (39%) | catalogued as rs368640809, COSV100494320; called by muse, mutect2, varscan2
- DDX41 | c.885C>T p.A295= | Silent (SNP) | VAF 94/316 reads (30%) | catalogued as COSV57251499; called by muse, mutect2, varscan2
- DDX47 | c.411G>A p.L137= | Silent (SNP) | VAF 32/216 reads (15%) | catalogued as COSV61911332; called by muse, mutect2, varscan2
- DHX37 | c.438C>A p.L146= | Silent (SNP) | VAF 41/230 reads (18%) | catalogued as COSV58133002; called by muse, mutect2, varscan2
- DSG4 | c.2122C>A p.R708= | Silent (SNP) | VAF 102/712 reads (14%) | catalogued as COSV57391550, COSV57397868; called by muse, mutect2, varscan2
- FAHD1 | c.207C>T p.H69= | Silent (SNP) | VAF 51/235 reads (22%) | catalogued as rs148244001; called by muse, mutect2, varscan2
- FANCM | c.1008G>T p.L336= | Silent (SNP) | VAF 150/412 reads (36%) | catalogued as COSV57498746; called by muse, mutect2, varscan2
- FHDC1 | c.3342G>A p.K1114= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as rs1443828797, COSV52598724; called by muse, mutect2, varscan2
- FHL2 | c.798G>A p.E266= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as COSV59079058; called by muse, mutect2
- FLNC | c.7611C>A p.A2537= | Silent (SNP) | VAF 58/352 reads (16%) | catalogued as rs1217693154, COSV57952818; called by muse, mutect2, varscan2
- FMO1 | c.1047G>A p.Q349= | Silent (SNP) | VAF 73/473 reads (15%) | catalogued as COSV61445113; called by muse, mutect2, varscan2
- FZD10 | c.1650G>C p.V550= | Silent (SNP) | VAF 38/301 reads (13%) | catalogued as COSV57472671; called by muse, mutect2, varscan2
- GFPT1 | c.1050G>A p.Q350= (on ENST00000357308 / NM_001244710.2; = p.Q332= on NM_002056.4) | Silent (SNP) | VAF 72/363 reads (20%) | catalogued as COSV61947153; called by muse, mutect2, varscan2
- GRM2 | c.1119G>A p.E373= | Silent (SNP) | VAF 51/257 reads (20%) | catalogued as rs778870495, COSV56583734; called by muse, mutect2, varscan2
- HHIPL2 | c.201C>T p.F67= | Silent (SNP) | VAF 67/536 reads (13%) | catalogued as rs777269842, COSV58563882; called by muse, mutect2, varscan2
- HPSE | c.720G>A p.S240= | Silent (SNP) | VAF 43/237 reads (18%) | catalogued as rs150778862; called by muse, mutect2, varscan2
- IFNAR1 | c.1245G>T p.L415= | Silent (SNP) | VAF 30/217 reads (14%) | catalogued as COSV54251308; called by muse, mutect2, varscan2
- INHBE | c.486C>T p.H162= | Silent (SNP) | VAF 70/365 reads (19%) | called by muse, mutect2, varscan2
- IQCB1 | c.1113C>T p.L371= | Silent (SNP) | VAF 65/347 reads (19%) | catalogued as rs1257528843, COSV100181576; called by muse, mutect2, varscan2
- ITGA8 | c.1962G>A p.S654= | Silent (SNP) | VAF 51/499 reads (10%) | catalogued as rs774254274, COSV65225668, COSV65226356; called by muse, mutect2, varscan2
- KCNB2 | c.1428C>A p.A476= | Silent (SNP) | VAF 69/330 reads (21%) | catalogued as COSV73049463; called by muse, mutect2, varscan2
- KCNJ4 | c.192G>T p.A64= | Silent (SNP) | VAF 35/149 reads (23%) | catalogued as COSV57856512; called by muse, mutect2, varscan2
- KNDC1 | c.1860G>A p.V620= | Silent (SNP) | VAF 36/311 reads (12%) | called by muse, mutect2, varscan2
- MAGEB6B | c.573C>T p.D191= | Silent (SNP) | VAF 77/257 reads (30%) | catalogued as rs755484263; called by muse, mutect2, varscan2
- MGAM2 | c.6567T>A p.T2189= | Silent (SNP) | VAF 78/334 reads (23%) | called by muse, mutect2, varscan2
- MICAL3 | c.2544C>T p.G848= | Silent (SNP) | VAF 60/192 reads (31%) | catalogued as rs569095141, COSV52894409; called by muse, mutect2
- MRPS18B | c.21C>T p.N7= | Silent (SNP) | VAF 73/458 reads (16%) | called by muse, mutect2, varscan2
- NLN | c.882C>T p.L294= | Silent (SNP) | VAF 62/443 reads (14%) | catalogued as rs777445413, COSV66765242; called by muse, mutect2, varscan2
- NOD1 | c.2169G>T p.L723= | Silent (SNP) | VAF 41/195 reads (21%) | called by muse, mutect2
- NPTXR | c.822G>A p.L274= | Silent (SNP) | VAF 51/224 reads (23%) | catalogued as COSV60727965; called by muse, mutect2, varscan2
- NTNG2 | c.1008G>T p.L336= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV62365526; called by muse, mutect2, varscan2
- NWD1 | c.2496A>G p.Q832= | Silent (SNP) | VAF 216/498 reads (43%) | catalogued as COSV60339650; called by muse, varscan2
- OR10Z1 | c.171C>G p.T57= | Silent (SNP) | VAF 33/220 reads (15%) | catalogued as COSV63524208; called by muse, mutect2, varscan2
- OR2T27 | c.297C>A p.A99= | Silent (SNP) | VAF 71/491 reads (14%) | called by muse, mutect2
- OR4K2 | c.207T>C p.I69= | Silent (SNP) | VAF 39/310 reads (13%) | called by muse, mutect2, varscan2
- OXGR1 | c.247C>T p.L83= | Silent (SNP) | VAF 31/223 reads (14%) | catalogued as COSV53657061; called by muse, mutect2, varscan2
- PCARE | c.1800C>A p.L600= | Silent (SNP) | VAF 90/778 reads (12%) | called by muse, mutect2, varscan2
- PDE4D | c.297G>T p.G99= | Silent (SNP) | VAF 127/340 reads (37%) | catalogued as COSV61424841; called by muse, mutect2, varscan2
- PEG3 | c.3576C>A p.S1192= | Silent (SNP) | VAF 106/336 reads (32%) | catalogued as COSV55629109, COSV99688099; called by muse, mutect2, varscan2
- PHACTR1 | c.762A>T p.P254= | Silent (SNP) | VAF 129/338 reads (38%) | catalogued as COSV60662446; called by muse, mutect2, varscan2
- PIEZO2 | c.6930C>T p.I2310= | Silent (SNP) | VAF 129/252 reads (51%) | catalogued as COSV53287592; called by muse, mutect2, varscan2
- POU4F1 | c.267G>A p.P89= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs1274250298; called by muse, mutect2, varscan2
- PSG1 | c.852C>A p.P284= | Silent (SNP) | VAF 195/977 reads (20%) | called by muse, mutect2, varscan2
- PZP | c.966C>A p.I322= | Silent (SNP) | VAF 79/375 reads (21%) | catalogued as COSV54356861; called by muse, mutect2, varscan2
- RIN3 | c.1425A>T p.P475= | Silent (SNP) | VAF 34/283 reads (12%) | called by muse, mutect2, varscan2
- RYR1 | c.10170C>A p.G3390= | Silent (SNP) | VAF 158/482 reads (33%) | catalogued as COSV62092988; called by muse, mutect2, varscan2
- RYR3 | c.231A>G p.R77= | Silent (SNP) | VAF 38/308 reads (12%) | called by muse, mutect2, varscan2
- SACS | c.1881G>T p.T627= | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as COSV66537085; called by muse, mutect2, varscan2
- SFMBT2 | c.366C>T p.D122= | Silent (SNP) | VAF 102/1230 reads (8%) | catalogued as rs554112272, COSV62806954; called by muse, mutect2
- SGCZ | c.300A>T p.L100= | Silent (SNP) | VAF 68/213 reads (32%) | catalogued as COSV66003667; called by muse, mutect2, varscan2
- SLC5A5 | c.669C>A p.A223= | Silent (SNP) | VAF 272/601 reads (45%) | catalogued as COSV55831996; called by muse, mutect2, varscan2
- SLC7A11 | c.1350A>C p.T450= | Silent (SNP) | VAF 140/362 reads (39%) | called by muse, varscan2
- STAP2 | c.1122A>G p.S374= (on ENST00000594605 / NM_001013841.2; = p.S420= on NM_017720.3) | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV55695366; called by muse, mutect2, varscan2
- TBX3 | c.1974C>T p.T658= (on ENST00000257566 / NM_016569.4; = p.T638= on NM_005996.4) | Silent (SNP) | VAF 47/250 reads (19%) | catalogued as rs1387417850, COSV57470134; called by muse, mutect2, varscan2
- TENM2 | c.762C>A p.P254= (on ENST00000518659 / NM_001122679.2; = p.P63= on NM_001080428.3) | Silent (SNP) | VAF 243/582 reads (42%) | catalogued as COSV69125566; called by muse, mutect2, varscan2
- TENM2 | c.6315C>A p.P2105= (on ENST00000518659 / NM_001122679.2; = p.P1866= on NM_001080428.3) | Silent (SNP) | VAF 63/375 reads (17%) | catalogued as COSV69125581, COSV69144715; called by muse, mutect2, varscan2
- TRIM3 | c.1755G>A p.R585= | Silent (SNP) | VAF 105/224 reads (47%) | catalogued as COSV61983416; called by muse, mutect2, varscan2
- UNC5C | c.690A>T p.R230= | Silent (SNP) | VAF 30/297 reads (10%) | catalogued as COSV71658778; called by muse, mutect2, varscan2
- UVSSA | c.273G>T p.L91= | Silent (SNP) | VAF 141/380 reads (37%) | catalogued as COSV66229238, COSV66229518; called by muse, mutect2, varscan2
- ZC3H7B | c.1818C>T p.R606= | Silent (SNP) | VAF 45/241 reads (19%) | catalogued as COSV60961114; called by muse, mutect2, varscan2
- ZNF347 | c.1332A>T p.L444= | Silent (SNP) | VAF 132/421 reads (31%) | catalogued as COSV61968020; called by muse, mutect2, varscan2
- ZNF423 | c.3630G>T p.L1210= (on ENST00000563137 / NM_001379286.1; = p.L1202= on NM_015069.4) | Silent (SNP) | VAF 65/357 reads (18%) | catalogued as COSV52182205; called by muse, mutect2, varscan2
- ZNF423 | c.2661G>A p.V887= (on ENST00000563137 / NM_001379286.1; = p.V879= on NM_015069.4) | Silent (SNP) | VAF 69/457 reads (15%) | catalogued as COSV52182221; called by muse, mutect2, varscan2
- ZNF598 | c.552T>C p.R184= | Silent (SNP) | VAF 204/614 reads (33%) | catalogued as COSV70910161; called by muse, mutect2, varscan2
- ABCC1 | c.1913-54G>T | Intron (SNP) | VAF 70/191 reads (37%) | called by muse, mutect2, varscan2
- AC022415.2 | c.*1822G>A | 3'UTR (SNP) | VAF 85/219 reads (39%) | called by muse, mutect2, varscan2
- AC099654.5 | n.10G>T | RNA (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- AC114741.1 | n.403G>A | RNA (SNP) | VAF 39/358 reads (11%) | called by muse, mutect2, varscan2
- AC116351.1 | n.1126G>T | RNA (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- ADAM6 | n.1286G>T | RNA (SNP) | VAF 258/675 reads (38%) | catalogued as rs1267699603; called by muse, mutect2, varscan2
- ADGRG1 | c.*34A>G | 3'UTR (SNP) | VAF 129/355 reads (36%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1072C>A | Intron (SNP) | VAF 103/273 reads (38%) | catalogued as COSV63750972, COSV63754724; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826770 A>T | 3'Flank (SNP) | VAF 122/211 reads (58%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845817 G>T | 5'Flank (SNP) | VAF 106/185 reads (57%) | called by muse, mutect2, varscan2
- ATP1A3 | c.-17G>T | 5'UTR (SNP) | VAF 89/290 reads (31%) | called by muse, mutect2, varscan2
- CD160 | c.538+17C>A | Intron (SNP) | VAF 138/499 reads (28%) | called by muse, mutect2, varscan2
- CHD8 | c.6771+254C>T | Intron (SNP) | VAF 30/165 reads (18%) | called by muse, mutect2, varscan2
- CHRNA4 | c.383+386G>T | Intron (SNP) | VAF 87/283 reads (31%) | called by muse, mutect2, varscan2
- CUBN | c.489+55C>T | Intron (SNP) | VAF 45/432 reads (10%) | called by muse, mutect2, varscan2
- CYP7B1 | c.*12G>T | 3'UTR (SNP) | VAF 25/198 reads (13%) | catalogued as COSV59582245; called by muse, mutect2, varscan2
- CYYR1 | c.-234C>A | 5'UTR (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- DST | c.4297-1929G>A | Intron (SNP) | VAF 67/346 reads (19%) | catalogued as rs200347043, COSV55004610; called by muse, mutect2, varscan2
- EIPR1 | c.259+19153G>T | Intron (SNP) | VAF 77/379 reads (20%) | called by muse, mutect2, varscan2
- FADS3 | c.983+146G>A | Intron (SNP) | VAF 9/49 reads (18%) | catalogued as rs756538564; called by muse, mutect2, varscan2
- FAM71E2 | c.*26G>T | 3'UTR (SNP) | VAF 76/217 reads (35%) | called by muse, mutect2, varscan2
- FAM90A20P | n.453G>A | RNA (SNP) | VAF 198/1066 reads (19%) | catalogued as rs759136585; called by muse, mutect2, varscan2
- FBXL13 | c.-1+487A>T | Intron (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
- GP6 | c.*102C>G | 3'UTR (SNP) | VAF 265/907 reads (29%) | catalogued as COSV59976819; called by muse, mutect2, varscan2
- GPER1 | c.*155C>A | 3'UTR (SNP) | VAF 233/521 reads (45%) | catalogued as rs1471434638; called by muse, mutect2, varscan2
- HHAT | c.-75T>A | 5'UTR (SNP) | VAF 21/59 reads (36%) | catalogued as COSV54793735; called by muse, mutect2, varscan2
- HLA-E | c.64+51C>T | Intron (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- ING5 | c.388+9G>T | Intron (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- ITGAD | c.858+19C>T | Intron (SNP) | VAF 81/189 reads (43%) | catalogued as rs1244853074; called by muse, mutect2, varscan2
- LILRB5 | c.1255+103G>T | Intron (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- MEG3 | chr14:100860743 C>A | 3'Flank (SNP) | VAF 46/293 reads (16%) | called by muse, mutect2, varscan2
- NANS | c.349-13_349-12del | Intron (DEL) | VAF 26/171 reads (15%) | catalogued as rs1303362895; called by pindel, varscan2
- NRXN1 | c.3719-1395C>T | Intron (SNP) | VAF 61/306 reads (20%) | catalogued as rs1169668668, COSV100640636; called by muse, mutect2, varscan2
- OPN1LW | c.-21G>A | 5'UTR (SNP) | VAF 263/518 reads (51%) | catalogued as COSV100886863; called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157747 G>T | 3'Flank (SNP) | VAF 204/1327 reads (15%) | called by muse, mutect2, varscan2
- PPFIA1 | c.1213-408C>G | Intron (SNP) | VAF 116/245 reads (47%) | catalogued as rs1240597157; called by muse, mutect2, varscan2
- PRKACB | c.47-5836C>T | Intron (SNP) | VAF 17/161 reads (11%) | catalogued as COSV65759130; called by muse, mutect2
- PRSS37 | c.430+220G>C | Intron (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- PSG6 | c.706+25A>C | Intron (SNP) | VAF 140/454 reads (31%) | called by muse, mutect2, varscan2
- RBFOX1 | c.351+152611T>A | Intron (SNP) | VAF 63/176 reads (36%) | catalogued as rs577322854; called by muse, mutect2, varscan2
- SCOC-AS1 | n.6613G>A | RNA (SNP) | VAF 114/311 reads (37%) | called by muse, mutect2, varscan2
- TFAP2B | c.*28G>T | 3'UTR (SNP) | VAF 47/271 reads (17%) | catalogued as COSV99539722; called by muse, mutect2, varscan2
- TNNI3K | c.*9G>T | 3'UTR (SNP) | VAF 35/153 reads (23%) | catalogued as COSV100436393; called by muse, mutect2, varscan2
- TRAPPC13 | c.546+14G>T | Intron (SNP) | VAF 36/236 reads (15%) | called by muse, mutect2, varscan2
- TXNRD1 | c.415-1322C>G | Intron (SNP) | VAF 230/675 reads (34%) | called by muse, mutect2, varscan2
- UBALD1 | c.120+140C>T | Intron (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- UMPS | c.*750A>G | 3'UTR (SNP) | VAF 56/334 reads (17%) | called by muse, mutect2, varscan2
- USP32P1 | n.334+1049G>A | Intron (SNP) | VAF 62/561 reads (11%) | called by muse, mutect2, varscan2
- Unknown | chr21:16071209 C>A | IGR (SNP) | VAF 52/243 reads (21%) | called by muse, mutect2, varscan2
- ZNF254 | c.158-29G>A | Intron (SNP) | VAF 43/209 reads (21%) | catalogued as rs1264954508; called by muse, mutect2, varscan2
- ZNF971P | n.884G>T | RNA (SNP) | VAF 91/523 reads (17%) | called by muse, mutect2, varscan2
